Somatic mutation profile of tumor specimen TCGA-33-4538-01A (aliquot TCGA-33-4538-01A-01D-1267-08) from TCGA case TCGA-33-4538, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 66.2 years (24,174 days).
Specimen TCGA-33-4538-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7c3bb3a5-3e6f-46fd-aff3-4733f8180f62.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-33-4538-11A (Solid Tissue Normal), aliquot TCGA-33-4538-11A-01D-1267-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0bfa1b79-8d5b-4e4b-b0e9-b7fd7db05c47

The open-access MAF lists 201 somatic variants for this specimen: 153 protein-altering or splice-affecting, 47 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 127, Silent 47, Nonsense Mutation 13, Frame Shift Del 5, Splice Site 4, Splice Region 2, Translation Start Site 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- INF2 | c.254C>T p.S85L | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1317776692, CM159472, COSV57981525; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.641A>G p.H214R | Missense Mutation (SNP) | VAF 60/82 reads (73%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as rs1057519992, CM103210, COSV52670202, COSV52732998, COSV52834506, COSV52887765; ClinVar: likely pathogenic; called by muse, varscan2
- ABCA8 | c.1861G>T p.E621* | Nonsense Mutation (SNP) | VAF 11/55 reads (20%) | catalogued as COSV52202697; called by muse, mutect2, varscan2
- ABCC9 | c.4319C>G p.A1440G | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.884); catalogued as COSV53973961, COSV53978051; called by muse, mutect2, varscan2
- ACAP2 | c.1430G>A p.R477Q | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV58751797; called by muse, mutect2, varscan2
- ACBD7 | c.194-1G>A p.X65_splice | Splice Site (SNP) | VAF 33/69 reads (48%) | catalogued as rs748375181, COSV62252196; called by muse, mutect2, varscan2
- ACKR2 | c.289G>T p.V97L | Missense Mutation (SNP) | VAF 108/168 reads (64%) | SIFT tolerated (0.71); PolyPhen benign (0.145); catalogued as COSV56178145; called by muse, mutect2, varscan2
- AL136295.1 | c.1344C>G p.I448M | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55779879; called by muse, mutect2, varscan2
- ANKRD24 | c.3070G>A p.E1024K | Missense Mutation (SNP) | VAF 81/253 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.157); catalogued as COSV53671440; called by muse, mutect2, varscan2
- APOB | c.6731G>T p.S2244I | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM104756, COSV51937929; called by muse, mutect2, varscan2
- ARHGEF6 | c.808C>A p.P270T | Missense Mutation (SNP) | VAF 26/35 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV51691645; called by muse, varscan2
- ARID3A | c.733C>G p.L245V | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV55044664, COSV99708393; called by muse, mutect2, varscan2
- ASB5 | c.659T>C p.L220P | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56671205; called by muse, mutect2, varscan2
- ATG2B | c.4652A>C p.K1551T | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV55890651; called by muse, mutect2, varscan2
- ATP10A | c.2150G>A p.R717Q | Missense Mutation (SNP) | VAF 47/155 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754138281, COSV63515638; called by muse, mutect2, varscan2
- ATP2B1 | c.543T>A p.F181L | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53808225; called by muse, mutect2, varscan2
- BRINP3 | c.1699C>T p.P567S | Missense Mutation (SNP) | VAF 70/176 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV66526222; called by muse, mutect2, varscan2
- BTNL3 | c.570T>A p.D190E | Missense Mutation (SNP) | VAF 26/35 reads (74%) | SIFT tolerated (0.05); PolyPhen benign (0.267); catalogued as COSV61565013; called by muse, mutect2, varscan2
- C20orf96 | c.419C>T p.T140M (on ENST00000360321 / NM_153269.3; = p.T139M on NM_080571.1) | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.236); catalogued as COSV64403671; called by muse, mutect2, varscan2
- CAPN3 | c.1502C>G p.T501S | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.955); catalogued as rs751104396, COSV58822719; called by muse, mutect2, varscan2
- CCDC43 | c.217C>T p.L73F | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV59519629; called by muse, varscan2
- CCNB3 | c.1190G>C p.R397P | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV52069879, COSV52074441; called by muse, mutect2
- CD180 | c.1681C>T p.R561C | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.169); catalogued as rs150000308, COSV99842143; called by muse, mutect2, varscan2
- CDH12 | c.814+1G>A p.X272_splice | Splice Site (SNP) | VAF 12/86 reads (14%) | catalogued as COSV66409667; called by mutect2, varscan2
- CDKN2A | c.244del p.V82Cfs*64 | Frame Shift Del (DEL) | VAF 16/42 reads (38%) | catalogued as COSV58682703, COSV58715254, COSV58723757; called by mutect2, pindel*, varscan2
- CDON | c.2257G>A p.A753T | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54998602; called by muse, mutect2, varscan2
- CEP152 | c.992C>G p.T331R | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV57860056; called by muse, mutect2, varscan2
- CFAP54 | c.5338G>A p.E1780K | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV61572436; called by muse, mutect2, varscan2
- CHRNA3 | c.709A>G p.I237V | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV58775500; called by muse, mutect2, varscan2
- CHST6 | c.766G>A p.A256T | Missense Mutation (SNP) | VAF 49/104 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs750187166, COSV60000556; called by muse, mutect2, varscan2
- CHST9 | c.749A>T p.H250L | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52438586; called by muse, mutect2, varscan2
- CHSY1 | c.2030A>G p.N677S | Missense Mutation (SNP) | VAF 57/180 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.048); catalogued as rs778446867, COSV54253697; called by muse, mutect2, varscan2
- CLRN2 | c.548A>G p.E183G | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV71825221; called by muse, mutect2, varscan2
- CMPK2 | c.919T>C p.Y307H | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56774936; called by muse, mutect2, varscan2
- COBL | c.1788A>T p.E596D | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as COSV54347514; called by muse, mutect2, varscan2
- COL11A1 | c.2488C>T p.Q830* | Nonsense Mutation (SNP) | VAF 13/50 reads (26%) | catalogued as COSV62185027; called by muse, mutect2, varscan2
- COL22A1 | c.3869G>A p.R1290Q | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as rs756748110, COSV57326618, COSV57327644; called by mutect2, varscan2
- COL6A2 | c.1451G>C p.G484A | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV56006705; called by muse, mutect2, varscan2
- CR2 | c.1892A>T p.Y631F | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as COSV65507910; called by muse, mutect2, varscan2
- CR2 | c.1893T>A p.Y631* | Nonsense Mutation (SNP) | VAF 33/70 reads (47%) | catalogued as rs1331358695, COSV65507914; called by muse, mutect2, varscan2
- CYP2B6 | c.606C>G p.F202L | Missense Mutation (SNP) | VAF 41/133 reads (31%) | SIFT tolerated (0.81); PolyPhen benign (0.045); catalogued as COSV57843833; called by muse, mutect2, varscan2
- CYP2C8 | c.978G>T p.E326D | Missense Mutation (SNP) | VAF 40/62 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64877389, COSV64879136; called by muse, mutect2, varscan2
- DIS3L | c.2298G>T p.M766I (on ENST00000319212 / NM_001143688.3; = p.M683I on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59912552; called by muse, mutect2, varscan2
- DNAJB1 | c.391T>G p.F131V | Missense Mutation (SNP) | VAF 98/228 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.901); catalogued as COSV54317106; called by muse, mutect2, varscan2
- DPH6 | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV56615035; called by muse, mutect2, varscan2
- DPP8 | c.681G>T p.W227C (on ENST00000341861 / NM_001320875.2; = p.W211C on NM_017743.6) | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV55679271, COSV55682004; called by muse, mutect2, varscan2
- DYNC1I1 | c.1411G>A p.G471R | Missense Mutation (SNP) | VAF 86/238 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61461879; called by muse, mutect2, varscan2
- EFR3A | c.1676C>G p.T559S | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.78); PolyPhen benign (0.042); catalogued as COSV54458116; called by muse, mutect2, varscan2
- EGR3 | c.268G>T p.A90S | Missense Mutation (SNP) | VAF 54/238 reads (23%) | SIFT tolerated (1); PolyPhen possibly damaging (0.487); catalogued as COSV57832941, COSV57833560; called by muse, varscan2
- EMILIN3 | c.1298A>G p.D433G | Missense Mutation (SNP) | VAF 92/295 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1177805912, COSV60036618; called by muse, varscan2
- EPS15 | c.66C>G p.Y22* | Nonsense Mutation (SNP) | VAF 12/18 reads (67%) | catalogued as COSV65531287; called by muse, mutect2, varscan2
- EVC2 | c.3262C>A p.H1088N | Missense Mutation (SNP) | VAF 103/177 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.236); catalogued as COSV60394927; called by muse, mutect2, varscan2
- FBXW12 | c.653T>C p.L218P | Missense Mutation (SNP) | VAF 130/230 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV56484094; called by muse, mutect2, varscan2
- FRMPD2 | c.583G>T p.V195L | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.063); catalogued as COSV59718573; called by muse, mutect2, varscan2
- G3BP2 | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV62976494; called by muse, mutect2, varscan2
- GJA10 | c.436A>G p.K146E | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65355261; called by muse, mutect2, varscan2
- GJD4 | c.220C>T p.H74Y | Missense Mutation (SNP) | VAF 71/426 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as COSV58702631; called by muse, mutect2, varscan2
- GPR18 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 18/87 reads (21%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.066); catalogued as COSV61621251; called by muse, mutect2, varscan2
- GRIA4 | c.2475G>T p.L825F | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56899372; called by muse, mutect2, varscan2
- H2AC15 | c.73C>A p.Q25K | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.257); catalogued as COSV100356843, COSV57585771; called by muse, mutect2, varscan2
- HACE1 | c.1963A>T p.R655W | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV53503012; called by muse, mutect2, varscan2
- IGSF8 | c.1618G>A p.G540S | Missense Mutation (SNP) | VAF 60/202 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58758209; called by muse, mutect2, varscan2
- IL17A | c.373G>T p.E125* | Nonsense Mutation (SNP) | VAF 18/43 reads (42%) | catalogued as COSV60683916, COSV60684793; called by muse, mutect2, varscan2
- INSR | c.2018A>G p.Y673C | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57163877; called by muse, mutect2, varscan2
- IQUB | c.403G>T p.V135F | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.029); catalogued as rs368660926, COSV61239718, COSV61242677; called by muse, mutect2, varscan2
- KCNK18 | c.656C>T p.S219L | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.084); catalogued as rs866402119, COSV100572022, COSV57971966; called by muse, mutect2
- KCNT2 | c.1553+2T>G p.X518_splice | Splice Site (SNP) | VAF 11/42 reads (26%) | catalogued as COSV54082969; called by muse, mutect2, varscan2
- KDM6A | c.649A>G p.T217A | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.403); catalogued as COSV65040881; called by muse, mutect2, varscan2
- KDM6B | c.1408C>G p.P470A | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV54682234; called by muse, varscan2
- KEAP1 | c.929T>C p.L310P | Missense Mutation (SNP) | VAF 51/141 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV50291357; called by muse, mutect2, varscan2
- KRTAP19-3 | c.38A>G p.Y13C | Missense Mutation (SNP) | VAF 110/184 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.047); catalogued as COSV61854768; called by muse, mutect2, varscan2
- LPCAT2 | c.1268T>C p.L423S | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50896086; called by muse, mutect2, varscan2
- LRP6 | c.2570G>A p.R857H | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1409527630, COSV53788242, COSV53788282; called by muse, mutect2, varscan2
- LRRC8D | c.1709A>G p.N570S | Missense Mutation (SNP) | VAF 32/44 reads (73%) | SIFT tolerated (0.56); PolyPhen benign (0.05); catalogued as rs765538578, COSV61579574; called by muse, mutect2, varscan2
- LRRTM3 | c.370T>A p.F124I | Missense Mutation (SNP) | VAF 90/198 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV63666248; called by muse, mutect2, varscan2
- MAGEB18 | c.119C>T p.P40L | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV57464185; called by muse, mutect2, varscan2
- MAGEB2 | c.790C>G p.P264A | Missense Mutation (SNP) | VAF 19/24 reads (79%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.479); catalogued as rs767384723, COSV66780869; called by muse, mutect2, varscan2
- MOV10L1 | c.1366G>T p.A456S | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.205); catalogued as COSV53172765; called by muse, mutect2, varscan2
- MPI | c.773A>G p.N258S | Missense Mutation (SNP) | VAF 50/182 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60396931; called by muse, varscan2
- MYCBP2 | c.1A>T p.M1? (on ENST00000357337; = p.M39L on NM_015057.5) | Translation Start Site (SNP) | VAF 8/10 reads (80%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs756982068, COSV62021635; called by muse, varscan2
- NAPRT | c.934T>A p.Y312N | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52785477; called by muse, mutect2, varscan2
- NELL2 | c.1132G>T p.D378Y | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as COSV61576217; called by muse, mutect2, varscan2
- NLRP3 | c.2794G>T p.E932* | Nonsense Mutation (SNP) | VAF 29/112 reads (26%) | catalogued as COSV100275077, COSV60225287; called by muse, mutect2, varscan2
- NME8 | c.1331T>A p.I444K | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52250986; called by muse, mutect2, varscan2
- NOTCH2 | c.4044A>T p.Q1348H | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV56692849; called by muse, mutect2, varscan2
- NSD3 | c.1552T>C p.F518L | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV57619332; called by muse, mutect2, varscan2
- OR2T8 | c.794C>A p.S265Y | Missense Mutation (SNP) | VAF 41/148 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1461941877, COSV60662839, COSV60664665; called by muse, mutect2, varscan2
- OR4K15 | c.202C>G p.L68V (on ENST00000305051; = p.L44V on NM_001005486.1) | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as COSV59301638; called by muse, mutect2
- OR4S2 | c.745T>A p.F249I | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV56747116; called by muse, mutect2, varscan2
- OR4S2 | c.746T>A p.F249Y | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV56747124; called by muse, mutect2, varscan2
- OR5A2 | c.250T>C p.S84P | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.352); catalogued as COSV57391155; called by muse, mutect2, varscan2
- OR5B2 | c.290T>C p.V97A | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV56908418; called by muse, mutect2, varscan2
- OR5M8 | c.657C>A p.Y219* | Nonsense Mutation (SNP) | VAF 22/74 reads (30%) | catalogued as COSV59116962; called by muse, mutect2, varscan2
- OR8D1 | c.635T>C p.L212P | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs759099795, COSV63442413; called by muse, mutect2, varscan2
- P4HB | c.1466A>C p.E489A | Missense Mutation (SNP) | VAF 80/387 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.04); catalogued as rs148124283; called by muse, mutect2, varscan2
- P4HB | c.1465G>T p.E489* | Nonsense Mutation (SNP) | VAF 80/387 reads (21%) | catalogued as COSV58940752, COSV58941754; called by muse, mutect2, varscan2
- PAPLN | c.3766G>A p.E1256K (on ENST00000554301; = p.E1229K on NM_173462.4) | Missense Mutation (SNP) | VAF 101/220 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs370302251; called by muse, mutect2, varscan2
- PCDHGB5 | c.1659C>A p.D553E | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs770231108, COSV53960515; called by muse, mutect2
- PHACTR2 | c.281A>T p.N94I | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV59855039; called by muse, mutect2
- PLCL1 | c.461A>G p.E154G | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.027); catalogued as COSV70836561; called by muse, varscan2
- PLCL1 | c.512A>T p.N171I | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV70836619; called by muse, varscan2
- PLEKHG3 | c.1203A>T p.Q401H (on ENST00000394691; = p.Q457H on NM_001308147.2) | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.982); catalogued as COSV55980619; called by muse, mutect2, varscan2
- PLEKHH1 | c.2228G>T p.C743F | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV61283924; called by muse, mutect2, varscan2
- PLK4 | c.2811-1G>C p.X937_splice | Splice Site (SNP) | VAF 6/20 reads (30%) | catalogued as COSV54637730; called by mutect2, varscan2
- POPDC2 | c.679C>T p.R227* | Nonsense Mutation (SNP) | VAF 15/78 reads (19%) | catalogued as rs371366869; called by muse, mutect2, varscan2
- POTED | c.419T>A p.L140Q | Missense Mutation (SNP) | VAF 75/107 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV55048559; called by muse, mutect2, varscan2
- POU5F2 | c.190C>A p.P64T | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as COSV67938063; called by muse, mutect2, varscan2
- PPP1R15A | c.1684G>A p.V562I | Missense Mutation (SNP) | VAF 67/130 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.621); catalogued as COSV52339224; called by muse, mutect2, varscan2
- PRDM9 | c.168G>T p.R56S | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV57003441, COSV57007182; called by muse, mutect2, varscan2
- PRKD2 | c.805A>G p.I269V | Missense Mutation (SNP) | VAF 39/132 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV52187166; called by muse, mutect2, varscan2
- PROS1 | c.1060C>G p.L354V | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.096); catalogued as COSV67775537; called by muse, mutect2, varscan2
- PSMC2 | c.740A>C p.Q247P | Missense Mutation (SNP) | VAF 57/153 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53007656; called by muse, mutect2, varscan2
- PSMD2 | c.788C>T p.P263L | Missense Mutation (SNP) | VAF 128/206 reads (62%) | SIFT deleterious (0.04); PolyPhen benign (0.247); catalogued as COSV59530058; called by muse, mutect2, varscan2
- PSMD3 | c.1003G>A p.V335M | Missense Mutation (SNP) | VAF 40/178 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99227633; called by mutect2, varscan2
- PTPRB | c.142C>T p.Q48* | Nonsense Mutation (SNP) | VAF 8/26 reads (31%) | catalogued as COSV51734101; called by muse, mutect2, varscan2
- PTPRCAP | c.262G>A p.G88S | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.66); catalogued as COSV57050696; called by muse, mutect2, varscan2
- RABGAP1L | c.178G>T p.E60* | Nonsense Mutation (SNP) | VAF 17/100 reads (17%) | catalogued as COSV52298787; called by muse, mutect2, varscan2
- RBMS2 | c.631G>T p.D211Y | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as COSV56264174; called by muse, mutect2, varscan2
- RIMKLA | c.849T>A p.F283L | Missense Mutation (SNP) | VAF 17/227 reads (7%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.957); catalogued as COSV68909798; called by muse, mutect2
- RRP15 | c.13G>T p.A5S | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.057); catalogued as COSV65118004, COSV65118038; called by muse, mutect2, varscan2
- SDSL | c.177G>A p.M59I | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.011); catalogued as rs1367738005, COSV61884784; called by muse, mutect2, varscan2
- SGIP1 | c.809G>A p.G270E | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.24); catalogued as rs1553149992, COSV52770065, COSV52770365; called by muse, mutect2, varscan2
- SH2D4A | c.376A>C p.K126Q | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.08); catalogued as COSV56122843; called by muse, mutect2, varscan2
- SHOC1 | c.362T>C p.L121S | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.868); catalogued as rs1370828665, COSV59502447; called by muse, mutect2, varscan2
- SLC5A1 | c.1967C>A p.A656D | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.536); catalogued as COSV56685802; called by muse, mutect2, varscan2
- SLC6A3 | c.149C>T p.P50L | Missense Mutation (SNP) | VAF 64/201 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as rs146798197; called by muse, mutect2, varscan2
- SOX3 | c.391G>T p.G131C | Missense Mutation (SNP) | VAF 28/45 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV65168286; called by muse, mutect2, varscan2
- SREBF1 | c.974G>T p.R325L | Missense Mutation (SNP) | VAF 30/208 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55417053, COSV99889649; called by muse, mutect2, varscan2
- STK11IP | c.-28C>T | Splice Region (SNP) | VAF 6/34 reads (18%) | catalogued as rs374564435, COSV55250339; called by muse, mutect2, varscan2
- SUPT3H | c.469C>T p.Q157* (on ENST00000371460 / NM_181356.3; = p.Q146* on NM_003599.4 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 4/38 reads (11%) | catalogued as COSV60940585; called by muse, mutect2, varscan2
- TAAR1 | c.91G>C p.V31L | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV51588767; called by muse, mutect2, varscan2
- TBC1D23 | c.1894A>T p.I632L (on ENST00000394144 / NM_001199198.3; = p.I617L on NM_018309.5) | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.936); catalogued as COSV61368246; called by muse, mutect2, varscan2
- TCAF1 | c.2172G>A p.W724* | Nonsense Mutation (SNP) | VAF 22/167 reads (13%) | catalogued as COSV63517673; called by muse, mutect2, varscan2
- TJP1 | c.2011A>C p.I671L | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV62042446; called by muse, mutect2, varscan2
- TNN | c.156G>T p.K52N | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as COSV53427357; called by muse, mutect2, varscan2
- TRANK1 | c.1891C>G p.H631D | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV57152407; called by muse, mutect2
- USP4 | c.2567G>A p.C856Y | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as COSV55537456; called by muse, mutect2, varscan2
- VPS33A | c.1106A>T p.D369V | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV57357261; called by muse, mutect2, varscan2
- WNK2 | c.6161G>T p.R2054L (on ENST00000297954 / NM_001282394.1; = p.R2017L on NM_006648.3) | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52944238; called by muse, mutect2, varscan2
- WWC1 | c.2815G>T p.V939L | Missense Mutation (SNP) | VAF 68/142 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as COSV54651763; called by muse, mutect2, varscan2
- XRRA1 | c.2011G>C p.E671Q | Missense Mutation (SNP) | VAF 60/330 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.068); catalogued as COSV55132909; called by muse, mutect2, varscan2
- YTHDF3 | c.1393T>C p.F465L | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV72773541; called by muse, mutect2, varscan2
- ZBTB9 | c.798G>T p.E266D | Missense Mutation (SNP) | VAF 32/174 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV67702126; called by muse, mutect2, varscan2
- ZFHX4 | c.3200G>T p.R1067L | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750806468, COSV50894948; called by muse, mutect2, varscan2
- ZFHX4 | c.4577G>A p.G1526E | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs1486232527, COSV50557067, COSV50756866; called by muse, mutect2, varscan2
- ZGRF1 | c.4127G>C p.G1376A | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV71393209; called by muse, mutect2
- ZNF616 | c.12G>A p.Q4= | Splice Region (SNP) | VAF 54/90 reads (60%) | catalogued as COSV57511331; called by muse, varscan2
- ZNF662 | c.564G>T p.E188D | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.071); catalogued as rs774489250, COSV60241982; called by muse, mutect2, varscan2
- ZNF91 | c.203G>A p.G68E | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.057); catalogued as COSV56085469; called by muse, mutect2, varscan2
- CACNA1F | c.1208del p.G403Afs*41 | Frame Shift Del (DEL) | VAF 14/32 reads (44%) | called by pindel, varscan2
- MAGI1 | c.1695del p.N566Ifs*4 | Frame Shift Del (DEL) | VAF 20/53 reads (38%) | called by mutect2, pindel, varscan2
- NFE2L3 | c.1066del p.L356Ffs*6 | Frame Shift Del (DEL) | VAF 36/93 reads (39%) | called by mutect2, varscan2
- OR5W2 | c.493del p.R165Afs*33 | Frame Shift Del (DEL) | VAF 28/87 reads (32%) | called by mutect2, pindel, varscan2
- AARS1 | c.1032C>G p.G344= | Silent (SNP) | VAF 28/116 reads (24%) | catalogued as COSV55747659; called by muse, mutect2, varscan2
- ADAMTS12 | c.1566G>A p.E522= | Silent (SNP) | VAF 34/106 reads (32%) | catalogued as COSV100710811, COSV61264418; called by muse, mutect2, varscan2
- AIM2 | c.564C>T p.F188= | Silent (SNP) | VAF 37/180 reads (21%) | catalogued as COSV63700041; called by muse, varscan2
- APCDD1 | c.1317C>T p.N439= | Silent (SNP) | VAF 16/162 reads (10%) | catalogued as rs1432768773, COSV62372593; called by muse, mutect2
- ARRDC2 | c.225C>T p.Y75= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs370715491; called by muse, mutect2
- BIRC6 | c.12970C>T p.L4324= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV70199978, COSV70208172; called by muse, mutect2, varscan2
- C11orf24 | c.342G>A p.T114= | Silent (SNP) | VAF 17/77 reads (22%) | catalogued as rs549353420, COSV58505730; called by muse, mutect2, varscan2
- CAMTA1 | c.1155G>A p.A385= | Silent (SNP) | VAF 39/160 reads (24%) | catalogued as rs371856667; called by muse, mutect2, varscan2
- CCDC70 | c.465G>A p.E155= | Silent (SNP) | VAF 83/138 reads (60%) | catalogued as rs1342347978, COSV54430367; called by muse, mutect2, varscan2
- CDS2 | c.333T>A p.T111= | Silent (SNP) | VAF 9/173 reads (5%) | catalogued as COSV66896572; called by muse, mutect2
- CGREF1 | c.10T>C p.L4= | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as COSV53149993; called by muse, mutect2, varscan2
- DNAH11 | c.420T>C p.N140= | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as COSV60958720; called by muse, mutect2, varscan2
- DPH6 | c.540G>T p.L180= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV56615044; called by muse, mutect2, varscan2
- DYNC2I1 | c.2520T>C p.H840= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as rs775970946, COSV68105063; called by muse, mutect2, varscan2
- EXPH5 | c.3333A>G p.R1111= | Silent (SNP) | VAF 19/103 reads (18%) | catalogued as COSV56203083; called by muse, mutect2, varscan2
- FLRT2 | c.283C>T p.L95= | Silent (SNP) | VAF 28/138 reads (20%) | catalogued as COSV58142627; called by muse, mutect2, varscan2
- FRMPD1 | c.1878C>G p.T626= | Silent (SNP) | VAF 32/55 reads (58%) | catalogued as COSV66700587; called by muse, mutect2, varscan2
- GNAS | c.363T>G p.P121= | Silent (SNP) | VAF 36/95 reads (38%) | catalogued as COSV58336448; called by muse, mutect2, varscan2
- IGLV2-8 | c.285C>A p.T95= | Silent (SNP) | VAF 81/362 reads (22%) | called by muse, mutect2, varscan2
- IL4R | c.1806T>A p.G602= | Silent (SNP) | VAF 24/103 reads (23%) | catalogued as COSV50146029; called by muse, mutect2, varscan2
- IRF9 | c.693G>A p.V231= | Silent (SNP) | VAF 53/235 reads (23%) | catalogued as COSV60703320; called by muse, mutect2, varscan2
- ITIH2 | c.549C>T p.Y183= | Silent (SNP) | VAF 43/255 reads (17%) | catalogued as COSV64433442; called by muse, mutect2, varscan2
- KCNA2 | c.108G>C p.V36= | Silent (SNP) | VAF 48/255 reads (19%) | catalogued as COSV60370204; called by muse, mutect2, varscan2
- KCNT2 | c.1386T>C p.V462= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as rs1169270916, COSV54082982; called by muse, mutect2, varscan2
- KLRC1 | c.447G>C p.S149= | Silent (SNP) | VAF 21/185 reads (11%) | catalogued as COSV61725301, COSV61726154; called by muse, mutect2, varscan2
- LIG4 | c.1212G>A p.Q404= | Silent (SNP) | VAF 11/86 reads (13%) | catalogued as COSV63597178; called by muse, mutect2, varscan2
- MED1 | c.2613C>T p.N871= | Silent (SNP) | VAF 27/119 reads (23%) | catalogued as COSV56125351; called by muse, mutect2, varscan2
- NRXN2 | c.2241C>T p.N747= | Silent (SNP) | VAF 24/101 reads (24%) | catalogued as rs749229993, COSV55454659; called by muse, mutect2, varscan2
- OR2T34 | c.630C>A p.L210= | Silent (SNP) | VAF 91/493 reads (18%) | catalogued as COSV60900668; called by muse, mutect2, varscan2
- OR2W1 | c.600C>T p.F200= | Silent (SNP) | VAF 22/110 reads (20%) | catalogued as rs746122871, COSV65851542; called by muse, varscan2
- OR5V1 | c.465C>T p.N155= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as rs768437138, COSV65828226; called by muse, mutect2, varscan2
- OTX1 | c.834C>T p.H278= | Silent (SNP) | VAF 46/281 reads (16%) | catalogued as rs765508695, COSV56994959; called by muse, varscan2
- P4HB | c.1263C>G p.V421= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV58941761; called by muse, mutect2, varscan2
- PLCB3 | c.2860C>T p.L954= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV54189035; called by muse, mutect2
- PLG | c.870C>T p.T290= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as rs763256179, COSV51981688; called by muse, mutect2, varscan2
- PROKR1 | c.669G>T p.V223= | Silent (SNP) | VAF 42/211 reads (20%) | catalogued as COSV58137741; called by muse, mutect2, varscan2
- RMDN3 | c.1185C>T p.L395= | Silent (SNP) | VAF 37/121 reads (31%) | catalogued as COSV53023798, COSV99540235; called by muse, mutect2, varscan2
- SH2D5 | c.450C>T p.H150= (on ENST00000444387 / NM_001103161.2; = p.H66= on NM_001103160.2) | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as rs758244310, COSV66706834; called by muse, mutect2, varscan2
- SPAG9 | c.75C>T p.S25= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as rs918336052, COSV56236510; called by mutect2, varscan2
- SPTA1 | c.3117C>T p.F1039= | Silent (SNP) | VAF 19/85 reads (22%) | catalogued as COSV63753650; called by muse, mutect2, varscan2
- SPTBN4 | c.4158C>T p.G1386= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs370944456; called by muse, mutect2, varscan2
- TBCCD1 | c.1524G>A p.V508= | Silent (SNP) | VAF 183/316 reads (58%) | catalogued as COSV58662300; called by muse, mutect2, varscan2
- TTN | c.3696T>C p.D1232= (on ENST00000591111; = p.D1186= on NM_003319.4) | Silent (SNP) | VAF 27/50 reads (54%) | catalogued as COSV60104128; called by muse, mutect2, varscan2
- VHL | c.549G>A p.S183= | Silent (SNP) | VAF 23/35 reads (66%) | catalogued as rs193922614, COSV56551519; ClinVar: likely benign; called by muse, mutect2, varscan2
- XRCC4 | c.546G>C p.L182= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV56538969; called by muse, mutect2, varscan2
- ZFHX4 | c.4578G>T p.G1526= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV50896568; called by muse, mutect2, varscan2
- ZNF365 | c.675C>A p.A225= | Silent (SNP) | VAF 55/136 reads (40%) | catalogued as rs750714807, COSV67925556, COSV67925602; called by muse, mutect2, varscan2
- PLEKHA8P1 | n.1450G>A | RNA (SNP) | VAF 15/104 reads (14%) | called by muse, mutect2, varscan2
